CCDI case PBCMAJ — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/21157383-9167-4a5b-9d73-3e2c82550b5b

Demographics
Sex at birth: male; Race: white.

Diagnoses (1)
1. Choroid plexus carcinoma: ICD-O-3 morphology code: 9390/3; Tissue or organ of origin: Parietal lobe; Age at diagnosis: 0.4 years (162 days).

Biospecimens (3 samples)
- Sample 0DV14A: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DV14N: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DV150: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
